Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7695, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7695-01A (Primary Tumor).

Tumor: [REDACTED]
Normal: [REDACTED]
Slide: [REDACTED]

Microscopic Description:

Sections demonstrate a moderately hypercellular glial neoplasm. There is extensive infiltration through both gray and white matter. In the gray matter, perineuronal satellitosis is striking. In the unfrozen material, most of the tumor cells are seen to have perinuclear halos. They have round nuclei with moderate atypia. No mitotic figures are seen. There is no microvascular proliferation or necrosis.

Addendum Discussion:

The calculated MIB-1 labeling index ranges up to 5.0% in the most proliferative regions of tumor. A MIB-1 labeling index of 5.0% is considered borderline by some studies for grade II and grade II oligodendrogliomas. The low grade features exhibited by this oligodendroglioma are more consistent with a grade II tumor; however, in light of the borderline MIB-1 index, this neoplasm should be closely followed for anaplastic progression and/or recurrence.

Diagnosis:

Low Grade Oligodendroglioma (WHO grade II).
MIB-1 Labeling Index= 5.0%

Source: NCI Genomic Data Commons file b6e04564-e56b-41f2-b500-aa4f8de489c1 (TCGA-HT-7695.351859ED-9826-4414-958D-DAFC1F741A33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).